Gene-level copy-number profile of tumor specimen TCGA-DK-AA75-01A from TCGA case TCGA-DK-AA75, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 82.4 years (30,090 days).
Specimen TCGA-DK-AA75-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.6139457a-accf-4aad-a78a-ee1ad1f9ce60.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-AA75-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 362 have no estimate.
https://portal.gdc.cancer.gov/files/d9762ea8-fdd0-4653-ad6a-098f8f198699

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 515; copy number 1: 52; copy number 2: 7,591; copy number 3: 19,785; copy number 4: 12,654; copy number 5: 10,425; copy number 6: 6,868; copy number 7: 1,110; copy number 8: 397; copy number 9: 432; copy number 10: 141; copy number 11: 23; copy number 12: 43; copy number 13: 9; copy number 14: 78; copy number 15: 53; copy number 24: 1; copy number 33: 8; copy number 63: 22; copy number 70: 10; copy number 81: 21; copy number 89: 5; copy number 92: 8; copy number 93: 1; copy number 96: 4; copy number 104: 4; copy number 111: 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:9,480,608–9,576,275, 2 genes: AC092821.1, AC092821.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,371 genes in 38 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,751,232–5,090,899, 86 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr1:24,119,771–24,364,482, 5 genes, copy number 10: IL22RA1, IFNLR1, LINC02800, GRHL3-AS1, GRHL3.
- chr1:72,283,170–72,753,772, 1 gene, copy number 7 (within-gene range 5–7): AL513166.1.
- chr1:72,636,547–73,355,253, 8 genes, copy number 7: AL583808.1, RNU6-1246P, LINC02796, LINC02797, AL732618.1, KRT8P21, RN7SKP19, LINC01360.
- chr1:158,878,746–185,436,047, 619 genes, copy number 7–9 (broad region; genes not listed).
- chr1:186,828,949–201,385,784, 156 genes, copy number 8–10 (within-gene range 4–10) (broad region; genes not listed).
- chr2:38,814–1,367,613, 30 genes, copy number 7 (within-gene range 4–7): FAM110C, AC079779.1, SH3YL1, ACP1, ALKAL2, AC079779.2, AC079779.3, AC079779.4, LINC01865, AC105393.2, AC105393.1, LINC01874, AC093326.2, LINC01875, AC093326.1, TMEM18, TMEM18-DT, AC092159.3, AC092159.2, AC092159.1, AC116609.3, AC116609.2, AC116609.1, LINC01115, LINC01939, AC113607.1, SNTG2-AS1, SNTG2, AC114808.1, AC114808.2.
- chr2:86,784,610–99,322,741, 338 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr2:212,926,257–214,410,501, 10 genes, copy number 7 (within-gene range 5–7): MIR4776-1, MIR4776-2, AC108066.2, IKZF2, AC079610.1, LINC01953, AC079610.2, SPAG16-DT, SPAG16, MIR4438.
- chr3:12,153,068–13,283,281, 23 genes, copy number 14–33 (within-gene range 3–33): TIMP4, MTCO1P5, GSTM5P1, PPARG, AC091492.1, TSEN2, RNA5SP123, RNU6-377P, MKRN2OS, MKRN2, Metazoa_SRP, RAF1, CRIP1P1, TMEM40, KRT18P17, CAND2, AC034198.2, RPL32, SNORA7A, AC034198.1, LINC02022, IQSEC1, AC069271.1.
- chr3:14,402,576–14,556,075, 3 genes, copy number 10 (within-gene range 3–10): SLC6A6, GRIP2, RNU6-905P.
- chr3:32,391,698–34,873,854, 39 genes, copy number 7–12 (within-gene range 3–12): CMTM7, CMTM6, MIR548AY, AC104306.1, DYNC1LI1, AC104306.2, IGBP1P3, RPL30P4, CNOT10, CNOT10-AS1, SUGT1P2, RPL23AP43, TRIM71, CCR4, GLB1, SEC13P1, SUMO2P10, TMPPE, RN7SL296P, CRTAP, AC112211.1, SUSD5, AC123900.1, FBXL2, UBP1, RNU7-110P, RNA5SP128, CLASP2, COX6CP10, AC112220.1, SDAD1P3, AC112220.2, PDCD6IP, LINC01811, AC123023.2, AC123023.1, AC018359.1, AC007483.1, FECHP1.
- chr3:142,145,454–142,225,592, 2 genes, copy number 7: RNU6-425P, GK5.
- chr3:152,449,272–155,745,071, 46 genes, copy number 7–9 (within-gene range 4–9): Y_RNA, AC026347.1, AC092924.1, AC092924.2, ATP5MGP5, P2RY1, HMGN2P13, AC117394.1, AC117394.2, RAP2B, RN7SL300P, AC078788.1, AC078788.2, LINC02006, LINC02877, RNU6-901P, Y_RNA, AC068985.1, U8, RPL21P42, ARHGEF26-AS1, ARHGEF26, DHX36, AC134026.1, AC134026.2, GPR149, DDX50P2, AC092994.1, SYPL1P1, DYNLL1P5, RPL9P15, AC073359.2, AC073359.1, MME, MME-AS1, LINC01487, STRIT1, AC104831.1, PABPC1P10, PLCH1, AC108729.3, AC108729.2, AC108729.1, RN7SL715P, PLCH1-AS1, PLCH1-AS2.
- chr6:20,212,087–21,602,383, 21 genes, copy number 63: AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3.
- chr6:21,822,536–21,822,737, 1 gene, copy number 63: AL136313.1.
- chr6:147,660,703–147,953,937, 1 gene, copy number 7 (within-gene range 4–7): AL033504.1.
- chr6:148,001,716–149,245,554, 15 genes, copy number 7 (within-gene range 4–7): AL445123.2, AL445123.1, AL359382.1, AL359382.2, AL513164.1, SASH1, RNU6-1222P, CYP51A1P3, SNRPEP6, RPSAP40, UST, UST-AS1, UST-AS2, AL603766.1, AL031056.1.
- chr11:65,726,939–67,398,410, 95 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr11:67,353,629–67,354,348, 1 gene, copy number 8: AP003419.2.
- chr11:76,860,867–77,821,017, 19 genes, copy number 8 (within-gene range 3–8): ACER3, AP002498.1, B3GNT6, CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1.
- chr11:86,703,099–87,328,824, 15 genes, copy number 7–15 (within-gene range 3–15): AP003059.1, AP003059.2, PRSS23, MOB4P2, OR7E13P, AP000654.1, OR7E2P, AP001528.1, AP001528.2, FZD4, FZD4-DT, HNRNPCP8, TMEM135, XIAPP2, AP002967.1.
- chr12:65,466,820–65,642,372, 1 gene, copy number 24 (within-gene range 2–111): AC025419.1.
- chr12:65,589,111–65,613,000, 1 gene, copy number 111 (within-gene range 2–111): LINC02454.
- chr12:66,023,620–66,130,750, 5 genes, copy number 89: MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH.
- chr12:67,131,567–67,352,039, 5 genes, copy number 93–96: RAB11AP2, GGTA2P, CAND1, AC078983.1, MRPL40P1.
- chr12:67,929,235–68,234,686, 8 genes, copy number 92 (within-gene range 2–92): LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26.
- chr12:68,674,371–69,354,234, 21 genes, copy number 81: AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1.
- chr12:69,449,470–69,823,204, 10 genes, copy number 70 (within-gene range 3–70): LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP.
- chr12:70,180,338–70,354,993, 4 genes, copy number 104: LINC02821, AC092881.2, CNOT2, AC092881.1.
- chr13:19,026,001–19,032,626, 2 genes, copy number 7 (within-gene range 3–7): GTF2IP3, AL137001.1.
- chr14:22,630,929–22,644,352, 1 gene, copy number 7 (within-gene range 3–7): OR6J1.
- chr16:8,276,263–11,182,186, 73 genes, copy number 12–14 (within-gene range 5–14) (broad region; genes not listed).
- chr16:11,465,260–15,157,020, 99 genes, copy number 8–15 (within-gene range 4–15) (broad region; genes not listed).
- chr17:30,769,388–43,002,959, 582 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr17:46,029,916–46,225,389, 1 gene, copy number 10 (within-gene range 5–10): KANSL1.
- chr17:46,193,576–46,268,694, 5 genes, copy number 10: KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2, AC005829.1.
- chr17:74,877,302–75,133,043, 19 genes, copy number 9: FADS6, USH1G, OTOP2, OTOP3, HID1, HID1-AS1, CDR2L, MRPL58, RNU6-362P, KCTD2, ATP5PD, RN7SL573P, AC111186.1, TRIM80P, SLC16A5, Y_RNA, ARMC7, NT5C, AC022211.4.

Autosomal genes at a single copy (total copy number 1): 40. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
